Somatic mutation profile of tumor specimen ALCH-B2YD-TTP1-A (aliquot ALCH-B2YD-TTP1-A-2-0-D-A799-36) from ALCHEMIST case ALCH-B2YD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.1 years (27,442 days).
Specimen ALCH-B2YD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6556b16-436d-4a2c-8f8c-b670e09aea00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2YD-NB1-A (Blood Derived Normal), aliquot ALCH-B2YD-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9362033-44d6-42f2-ad70-838841a7985b

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Nonsense Mutation 2, 3'Flank 1, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57860145; called by muse, mutect2
- COL4A5 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086075; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs754135731; called by mutect2, varscan2*
- KCNH7 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs151139318; called by muse, mutect2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, mutect2
- ABCC11 | c.3777+2T>C p.X1259_splice | Splice Site (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- APCS | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- IFI16 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGSF1 | c.3766G>T p.E1256* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- MPC1L | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- PCDH11X | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TADA2B | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- TBX20 | c.1220A>T p.Q407L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRBC2 | c.135G>T p.W45C | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TREM2 | c.284T>G p.I95S | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- UNC80 | c.8513A>G p.D2838G | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZACN | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CNTNAP2 | c.2970T>C p.D990= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- JAM3 | c.42G>A p.R14= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs1406642313; called by muse, mutect2
- MYO6 | c.144G>C p.V48= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- NEB | c.11409G>A p.E3803= | Silent (SNP) | VAF 14/297 reads (5%) | called by muse, mutect2
- RAB33A | c.354C>T p.D118= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs892513764, COSV57061869; called by muse, mutect2
- SLFN11 | c.2190A>T p.I730= | Silent (SNP) | VAF 18/269 reads (7%) | catalogued as rs774376604, COSV57699392; called by muse, mutect2
- VCAM1 | c.207G>A p.G69= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV54118912; called by muse, mutect2, varscan2
- ZP4 | c.231A>T p.I77= | Silent (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- DYNC1LI1 | c.220+129C>T | Intron (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PPM1B | chr2:44232330 A>G | 3'Flank (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
